CPTAC case C3L-06538 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27cdc82d-d960-42a0-a0af-c1017aa30244

Demographics
Sex at birth: male; Race: white; Year of birth: 1954; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,821 days); Year of diagnosis: 2019; Days to last known disease status: 716 days (2.0 years); Progression or recurrence: no; Days to last follow up: 716 days (2.0 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 327 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 327 days; Karnofsky performance status: 70; ECOG performance status: 3.
- Days to follow up: 716 days (2.0 years); Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 67 kg; Height: 175 cm; BMI: 21.88.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples)
- Samples C3L-06538-51, C3L-06538-52, C3L-06538-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-06538-54, C3L-06538-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 310 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
